Somatic mutation profile of tumor specimen C3N-00333-03 (aliquot CPT0011000006) from CPTAC case C3N-00333, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 65.5 years (23,940 days).
Specimen C3N-00333-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8007b95-51dc-439a-82ea-83dfbd009a4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00333-31 (Blood Derived Normal), aliquot CPT0011100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d97df25f-82e2-4079-97f6-d4562e9312b4

The open-access MAF lists 59 somatic variants for this specimen: 38 protein-altering or splice-affecting, 15 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 15, Intron 4, Splice Site 3, Nonsense Mutation 3, Splice Region 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 76/388 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ESR1 | c.1387T>C p.S463P | Missense Mutation (SNP) | VAF 15/377 reads (4%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.963); catalogued as rs1057519714, COSV52784970; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 57/270 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- PTEN | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 103/281 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs398123320, COSV64297602, COSV64303463, COSV64307402; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C1S | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs782678322; called by muse, mutect2, varscan2
- GPR161 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs147802262; called by muse, mutect2, varscan2
- GPR34 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1393417949, COSV59372109; called by muse, mutect2, varscan2
- KDM4B | c.2039C>T p.T680M | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs149752315; called by muse, mutect2, varscan2
- KPTN | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs375504032; called by muse, mutect2, varscan2
- MMP13 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.053); catalogued as rs776309041, COSV52824513; called by muse, mutect2
- MMP28 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs369105121; called by muse, mutect2
- PHC1 | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs373875447; called by muse, mutect2, varscan2
- PIK3CA | c.334A>T p.I112F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV55908000; called by muse, mutect2, varscan2
- RBM17 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.885); catalogued as rs1303376462; called by muse, mutect2, varscan2
- SNRPC | c.250+1G>A p.X84_splice | Splice Site (SNP) | VAF 10/114 reads (9%) | catalogued as COSV55074874; called by muse, mutect2, varscan2
- TCF20 | c.5789C>G p.P1930R | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV100166400; called by muse, mutect2
- AC126283.2 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 62/422 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- DYNC2H1 | c.9847C>A p.P3283T | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEF2 | c.1393C>G p.P465A | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ERI2 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FOXP4 | c.1366C>T p.Q456* (on ENST00000307972 / NM_001012426.1; = p.Q443* on NM_138457.3) | Nonsense Mutation (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2, varscan2
- GPR107 | c.1262+2T>C p.X421_splice | Splice Site (SNP) | VAF 30/146 reads (21%) | called by muse, mutect2, varscan2
- GUCY2D | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- IDH3G | c.1019+4A>T | Splice Region (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- ING4 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2
- IRX2 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- MRRF | c.548C>G p.P183R | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MTUS2 | c.1022C>A p.S341* | Nonsense Mutation (SNP) | VAF 49/241 reads (20%) | called by muse, mutect2, varscan2
- OR5H2 | c.118T>A p.Y40N | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PLK1 | c.1270+2T>C p.X424_splice | Splice Site (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- PPP6C | c.801T>G p.N267K | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKDC | c.8982G>A p.W2994* | Nonsense Mutation (SNP) | VAF 35/269 reads (13%) | called by muse, mutect2, varscan2
- RPLP1 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- RYR2 | c.11091G>A p.K3697= | Splice Region (SNP) | VAF 24/304 reads (8%) | called by muse, mutect2
- TRIM24 | c.744G>T p.L248F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- UEVLD | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWA8 | c.2840T>C p.V947A | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DHX32 | c.1521A>G p.L507= | Silent (SNP) | VAF 25/262 reads (10%) | called by muse, mutect2
- ELAVL3 | c.195C>T p.I65= | Silent (SNP) | VAF 60/261 reads (23%) | catalogued as rs756001334; called by muse, mutect2, varscan2
- FCHO1 | c.642G>T p.L214= | Silent (SNP) | VAF 29/280 reads (10%) | called by muse, mutect2, varscan2
- GPAA1 | c.423C>T p.T141= | Silent (SNP) | VAF 10/193 reads (5%) | catalogued as rs782152642; called by muse, mutect2
- ITPRIP | c.1416G>A p.K472= | Silent (SNP) | VAF 34/208 reads (16%) | called by muse, mutect2, varscan2
- KIF2B | c.273G>A p.P91= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as rs372558151, COSV52128084; called by muse, mutect2, varscan2
- MGAM2 | c.5310C>T p.D1770= | Silent (SNP) | VAF 11/183 reads (6%) | catalogued as rs1272295729; called by muse, mutect2
- PCDH19 | c.636C>T p.D212= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as COSV55265938; called by muse, mutect2, varscan2
- PTPRN | c.2403C>T p.S801= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as rs755297927, COSV99834388; called by muse, mutect2
- ROBO2 | c.3216C>G p.V1072= | Silent (SNP) | VAF 33/207 reads (16%) | called by muse, mutect2, varscan2
- RPGRIP1 | c.2580C>T p.D860= | Silent (SNP) | VAF 35/152 reads (23%) | called by muse, mutect2, varscan2
- TCERG1 | c.3159T>C p.N1053= | Silent (SNP) | VAF 37/270 reads (14%) | catalogued as rs916549373; called by muse, mutect2, varscan2
- TPM3 | c.462C>T p.H154= | Silent (SNP) | VAF 73/447 reads (16%) | catalogued as COSV55134456, COSV55139104; called by muse, mutect2, varscan2
- UBE2D4 | c.15G>A p.R5= | Silent (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- VPS50 | c.1380G>A p.L460= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as COSV100004864; called by muse, mutect2
- ABCG1 | c.287-14785G>A | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- ATP13A5 | c.2526-23C>A | Intron (SNP) | VAF 26/200 reads (13%) | catalogued as rs745342887; called by muse, mutect2, varscan2
- MED15 | c.157-322C>A | Intron (SNP) | VAF 27/142 reads (19%) | called by muse, mutect2, varscan2
- MIR124-2HG | n.348G>A | RNA (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- NUP214 | c.6075-960G>T | Intron (SNP) | VAF 16/94 reads (17%) | called by muse, varscan2
- XIAP | c.*2978G>T | 3'UTR (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
